Somatic mutation profile of tumor specimen TCGA-43-2576-01A (aliquot TCGA-43-2576-01A-01W-0877-08) from TCGA case TCGA-43-2576, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-43-2576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1fdb9ce-60d6-4fa1-8cd0-64a1cf491f15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2576-11A (Solid Tissue Normal), aliquot TCGA-43-2576-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c9660a4-543c-4818-b3e7-700ba4c09986

The open-access MAF lists 529 somatic variants for this specimen: 414 protein-altering or splice-affecting, 104 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 347, Silent 104, Nonsense Mutation 36, Frame Shift Del 10, Splice Site 8, Splice Region 6, Frame Shift Ins 5, RNA 4, Intron 3, 5'Flank 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 54/151 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCA13 | c.11147C>A p.T3716K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101446788; called by muse, mutect2, varscan2
- ABCA9 | c.1792-1G>T p.X598_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100382645; called by muse, mutect2, varscan2
- ABCD2 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100429170; called by muse, mutect2, varscan2
- ABI3BP | c.2649G>A p.M883I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99425496; called by muse, mutect2, varscan2
- AC105001.2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100134684; called by muse, mutect2, varscan2
- ACAP2 | c.1323C>T p.H441= | Splice Region (SNP) | VAF 74/309 reads (24%) | catalogued as COSV100461494; called by muse, mutect2, varscan2
- ACTL9 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.274); catalogued as COSV100185125; called by muse, mutect2, varscan2
- ACTR5 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1202164711, COSV99709900; called by muse, mutect2, varscan2
- ACTRT1 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100947507; called by muse, mutect2, varscan2
- ADCY8 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53927119, COSV99650847; called by muse, varscan2
- ADGRF5 | c.2652C>G p.D884E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV51938893, COSV99344953; called by muse, mutect2, varscan2
- ADGRG4 | c.2155G>C p.A719P | Missense Mutation (SNP) | VAF 146/1058 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99794434; called by muse, mutect2, varscan2
- ADGRG4 | c.2790G>T p.M930I | Missense Mutation (SNP) | VAF 260/1492 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99794435; called by muse, mutect2, varscan2
- AGA | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS991287, COSV99219366; called by muse, mutect2, varscan2
- AGO3 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99868024; called by muse, mutect2, varscan2
- AGPAT1 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100421543; called by muse, mutect2, varscan2
- AHNAK | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99945704; called by muse, mutect2, varscan2
- AKAP6 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99798512; called by muse, mutect2, varscan2
- ALX4 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100240908; called by muse, mutect2, varscan2
- AMBN | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as COSV100534268; called by muse, mutect2, varscan2
- AMER1 | c.2592G>T p.W864C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57659346; called by muse, mutect2, varscan2
- ANK1 | c.3854T>C p.I1285T | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55895110, COSV99225894; called by muse, mutect2
- APBA1 | c.1439_1440insT p.V481Rfs*28 | Frame Shift Ins (INS) | VAF 102/393 reads (26%) | catalogued as COSV99595488; called by mutect2, pindel, varscan2
- ARHGEF12 | c.2143C>A p.P715T | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV100754670; called by muse, mutect2, varscan2
- ASB9 | c.67A>T p.R23W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100995378; called by muse, mutect2, varscan2
- ASCL1 | c.709T>A p.*237Rext*64 | Nonstop Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99901901; called by muse, mutect2, varscan2
- ATP2B3 | c.2985C>A p.N995K | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99683130; called by muse, mutect2, varscan2
- ATP2C1 | c.361-2A>T p.X121_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as CS077347, COSV100146301; called by muse, mutect2, varscan2
- ATP6V0A2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100376830; called by muse, mutect2, varscan2
- ATP7A | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 181/823 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430281; called by muse, mutect2, varscan2
- AWAT1 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as COSV100997175; called by muse, mutect2, varscan2
- BACH1 | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99727943, COSV99728427; called by muse, mutect2, varscan2
- BDP1 | c.2495A>T p.E832V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV62435824; called by muse, mutect2, varscan2
- BDP1 | c.2496G>T p.E832D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV100702747; called by muse, mutect2, varscan2
- BDP1 | c.5637C>G p.D1879E | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100702748; called by muse, mutect2, varscan2
- BEST2 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV50360669; called by muse, mutect2, varscan2
- BNIP5 | c.1803C>A p.Y601* | Nonsense Mutation (SNP) | VAF 43/168 reads (26%) | catalogued as COSV101465114; called by muse, mutect2, varscan2
- BPTF | c.8878G>A p.D2960N | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100074139; called by muse, mutect2, varscan2
- C10orf71 | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60504174, COSV60508433; called by muse, mutect2, varscan2
- C6orf118 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100024127; called by muse, mutect2, varscan2
- C8A | c.1613C>A p.A538E | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV63483590; called by muse, mutect2, varscan2
- CACNA1S | c.2633T>G p.V878G | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100754683; called by muse, mutect2, varscan2
- CACNA2D3 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99870584; called by muse, mutect2, varscan2
- CALN1 | c.522G>C p.E174D (on ENST00000329008 / NM_001017440.3; = p.E216D on NM_031468.4) | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100205010; called by muse, mutect2, varscan2
- CAMK2B | c.389T>A p.M130K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.209); catalogued as COSV99322775; called by muse, mutect2, varscan2
- CASP10 | c.1315G>T p.G439C (on ENST00000272879 / NM_032974.5; = p.G396C on NM_001230.5) | Missense Mutation (SNP) | VAF 94/419 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628745; called by muse, mutect2
- CATSPERE | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 55/435 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1307589732, COSV100834933; called by muse, mutect2, varscan2
- CBLL2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100081475, COSV100081801; called by muse, mutect2, varscan2
- CCDC110 | c.1844A>G p.Q615R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV100293683; called by muse, mutect2, varscan2
- CCL19 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs556438266, COSV100323118; called by muse, mutect2, varscan2
- CDKL5 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV101184045; called by muse, mutect2, varscan2
- CDKL5 | c.1912A>G p.R638G | Missense Mutation (SNP) | VAF 154/1058 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101184046; called by muse, mutect2, varscan2
- CDS2 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 16/609 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1330211301; called by muse, mutect2
- CDYL2 | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101629511; called by muse, mutect2, varscan2
- CEP85L | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100820995; called by muse, mutect2, varscan2
- CERS3 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs199763147, COSV52576684; called by muse, mutect2, varscan2
- CETN2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 26/204 reads (13%) | catalogued as COSV100938605; called by muse, mutect2, varscan2
- CFAP221 | c.2229C>A p.C743* | Nonsense Mutation (SNP) | VAF 62/221 reads (28%) | catalogued as COSV54653857, COSV99731948; called by muse, mutect2, varscan2
- CFAP47 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as rs781233621, COSV99934423; called by muse, mutect2, varscan2
- CHST6 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV100178265, COSV60001182; called by muse, mutect2, varscan2
- CLEC4M | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 150/441 reads (34%) | catalogued as COSV50216865, COSV99940363; called by muse, mutect2, varscan2
- CLPSL1 | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100870175; called by muse, varscan2
- CLSTN2 | c.1738C>G p.R580G | Missense Mutation (SNP) | VAF 94/423 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV71723325, COSV71725403; called by muse, mutect2, varscan2
- CNGA3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.122); catalogued as rs374938560, COSV55624287, COSV55627390; called by muse, mutect2, varscan2
- COL11A2 | c.3386G>T p.G1129V (on ENST00000341947 / NM_080680.3; = p.G1022V on NM_080679.2) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553478; called by muse, mutect2, varscan2
- COL12A1 | c.8840C>T p.P2947L | Missense Mutation (SNP) | VAF 78/476 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751239090, COSV59392201; called by muse, mutect2, varscan2
- COL13A1 | c.1427G>T p.G476V (on ENST00000398978 / NM_001130103.2; = p.G419V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637292; called by muse, mutect2, varscan2
- COL24A1 | c.3199C>G p.P1067A | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV100992915; called by muse, mutect2, varscan2
- COL27A1 | c.4664A>G p.K1555R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV100620743; called by muse, mutect2, varscan2
- CORO2A | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100673978; called by muse, mutect2, varscan2
- CPLANE1 | c.8765A>T p.E2922V | Missense Mutation (SNP) | VAF 133/1039 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949704; called by muse, mutect2, varscan2
- CPSF6 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV99879015; called by muse, mutect2, varscan2
- CR2 | c.2617G>T p.G873* | Nonsense Mutation (SNP) | VAF 31/233 reads (13%) | catalogued as COSV100889535, COSV100889550; called by muse, mutect2, varscan2
- CRHBP | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV57190637; called by muse, mutect2, varscan2
- CRIM1 | c.2962T>A p.S988T | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.073); catalogued as COSV99752480; called by muse, mutect2, varscan2
- CSMD1 | c.8455G>T p.E2819* (on ENST00000520002; = p.E2818* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV100144229, COSV59369563; called by muse, mutect2, varscan2
- CSMD3 | c.1639A>T p.T547S (on ENST00000297405 / NM_001363185.1; = p.T443S on NM_052900.3) | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs1392847353, COSV99825585; called by muse, mutect2, varscan2
- CTNNA2 | c.2074C>A p.Q692K | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV100559527, COSV58160643; called by muse, mutect2, varscan2
- CXorf21 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100973220; called by muse, mutect2, varscan2
- CYP2C8 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750902318, COSV100987882; called by muse, mutect2, varscan2
- DBN1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99445562; called by muse, mutect2, varscan2
- DCP1B | c.572A>C p.Y191S | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99767244; called by muse, mutect2, varscan2
- DDX60L | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs749222089, COSV99486987; called by muse, mutect2, varscan2
- DEUP1 | c.432G>A p.E144= | Splice Region (SNP) | VAF 26/151 reads (17%) | catalogued as COSV99976688; called by muse, mutect2, varscan2
- DGKB | c.1476A>T p.L492F | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51768356; called by muse, mutect2, varscan2
- DIO2 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70445005; called by muse, mutect2
- DISP3 | c.1008dup p.S337Qfs*19 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs1254844982; called by pindel, varscan2
- DNAH9 | c.10129T>A p.C3377S | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV99304261; called by muse, mutect2, varscan2
- DOCK10 | c.4840G>A p.V1614M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99287725; called by muse, mutect2
- DOCK4 | c.3153G>T p.M1051I | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV101447787; called by muse, mutect2, varscan2
- DPF3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 131/334 reads (39%) | catalogued as rs533714896, COSV63498537; called by muse, mutect2, varscan2
- DPP6 | c.18G>C p.M6I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.38); catalogued as COSV101341254, COSV101341966; called by muse, mutect2, varscan2
- DSG4 | c.1635T>C p.N545= | Splice Region (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100355372; called by muse, mutect2, varscan2
- DYTN | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101123939; called by muse, mutect2, varscan2
- EFHC2 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV101375441; called by muse, mutect2, varscan2
- EGFLAM | c.2506G>A p.E836K (on ENST00000354891 / NM_001205301.2; = p.E828K on NM_152403.4) | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV59299371; called by muse, mutect2, varscan2
- EHD2 | c.590C>G p.S197W | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99621645; called by muse, mutect2
- ELAVL2 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV99805497; called by muse, mutect2, varscan2
- EMILIN2 | c.2302C>A p.H768N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV99598144; called by muse, mutect2, varscan2
- ERICH3 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 262/1169 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100443465, COSV58599791; called by muse, mutect2, varscan2
- EYS | c.341G>C p.C114S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100675702, COSV100676978; called by muse, mutect2, varscan2
- F8 | c.2933C>A p.S978* | Nonsense Mutation (SNP) | VAF 63/329 reads (19%) | catalogued as CM111351, COSV100811257; called by muse, mutect2, varscan2
- FAM114A1 | c.657A>C p.T219= | Splice Region (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100729172; called by muse, mutect2, varscan2
- FAM114A1 | c.657+1G>A p.X219_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100729176; called by muse, mutect2, varscan2
- FAM135B | c.1265A>C p.N422T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1407161622, COSV99419320; called by muse, mutect2, varscan2
- FAM13C | c.74A>T p.D25V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); catalogued as COSV53253781; called by muse, mutect2
- FAM47A | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV100649779; called by muse, mutect2, varscan2
- FAM47C | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100792302; called by muse, varscan2
- FAM47C | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792303; called by muse, varscan2
- FAM71B | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 120/460 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100261823; called by muse, mutect2, varscan2
- FANCM | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99950487; called by muse, mutect2, varscan2
- FCGR2C | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100912527; called by muse, mutect2, varscan2
- FMR1 | c.1364C>A p.T455K | Missense Mutation (SNP) | VAF 62/521 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.122); catalogued as COSV99502968; called by muse, mutect2, varscan2
- FMR1 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.079); catalogued as rs1557181787, COSV54428027, COSV99502969; called by muse, mutect2, varscan2
- FNDC3B | c.3175+1G>T p.X1059_splice | Splice Site (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100393636; called by muse, varscan2
- FOLR1 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100398516; called by muse, mutect2
- FRMPD3 | c.4238del p.G1413Afs*12 | Frame Shift Del (DEL) | VAF 39/235 reads (17%) | catalogued as COSV52189566; called by mutect2, pindel, varscan2
- FRS2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100165752; called by muse, mutect2, varscan2
- FUT8 | c.1646G>T p.R549M (on ENST00000360689 / NM_001371534.1; = p.R386M on NM_004480.4) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV100651062; called by muse, mutect2, varscan2
- GABRD | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101059509; called by muse, mutect2
- GABRG1 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV54950653, COSV54950897; called by muse, mutect2, varscan2
- GABRG1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.309); catalogued as COSV99777450; called by muse, mutect2, varscan2
- GALK2 | c.786G>C p.W262C | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV100508621; called by muse, mutect2, varscan2
- GEMIN8 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256928; called by muse, mutect2, varscan2
- GJA8 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53790896; called by muse, mutect2, varscan2
- GOLGB1 | c.8717A>G p.Q2906R | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.964); catalogued as COSV100510360; called by muse, mutect2
- GPR148 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV99998509; called by muse, mutect2, varscan2
- GPR50 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); catalogued as COSV99505688; called by muse, mutect2, varscan2
- GPRASP1 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 67/712 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100850913; called by muse, mutect2
- GPRIN3 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100310601; called by muse, mutect2, varscan2
- GRIK3 | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV100901384; called by muse, mutect2, varscan2
- GRIK5 | c.1564A>T p.S522C | Missense Mutation (SNP) | VAF 151/548 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99490029; called by muse, mutect2, varscan2
- GRIN3A | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100701370; called by muse, mutect2, varscan2
- GSPT2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100467920, COSV61214028; called by muse, mutect2, varscan2
- GTF2E1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99381747; called by muse, mutect2, varscan2
- GTPBP8 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99868217; called by muse, mutect2, varscan2
- H1-6 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs150306409; called by muse, mutect2
- H2AC17 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); catalogued as rs369136451; called by muse, mutect2, varscan2
- HAO1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66492507; called by muse, mutect2, varscan2
- HAO1 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113137; called by muse, mutect2, varscan2
- HDAC6 | c.3541G>T p.A1181S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs782778504, COSV100490584; called by muse, mutect2, varscan2
- HDX | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV99946656; called by muse, mutect2, varscan2
- HELQ | c.861T>A p.S287R | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99787429; called by muse, mutect2, varscan2
- HEY2 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856299; called by muse, mutect2, varscan2
- HGF | c.531T>A p.C177* | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as COSV99735695; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.742G>T p.G248* (on ENST00000354667 / NM_031243.3; = p.G236* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100668213; called by muse, mutect2
- HSD17B10 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as rs1235902504; called by muse, mutect2
- ICOS | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100320277; called by muse, mutect2, varscan2
- IGFBP2 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99288298; called by muse, mutect2, varscan2
- IL1RL1 | c.610+1G>A p.X204_splice | Splice Site (SNP) | VAF 25/141 reads (18%) | catalogued as COSV99293641; called by muse, mutect2, varscan2
- IL1RL1 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99293645; called by muse, mutect2, varscan2
- IMPG1 | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100886069; called by muse, mutect2, varscan2
- IRS1 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100524036; called by muse, mutect2, varscan2
- ITCH | c.2152C>A p.H718N (on ENST00000262650 / NM_001257137.3; = p.H677N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99392026; called by muse, mutect2, varscan2
- ITGA6 | c.2854A>G p.R952G (on ENST00000442250; = p.R913G on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs770287742, COSV99905113; called by muse, mutect2, varscan2
- JPH3 | c.2224C>A p.L742M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99412864; called by muse, mutect2, varscan2
- KALRN | c.1998G>C p.E666D | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV99562286; called by muse, mutect2, varscan2
- KCNH4 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99236780; called by muse, mutect2, varscan2
- KCNH6 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.361); catalogued as COSV100120799; called by muse, mutect2, varscan2
- KCNIP4 | c.335A>C p.Y112S | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100749071; called by muse, mutect2, varscan2
- KCNK1 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV64035388; called by muse, mutect2, varscan2
- KCNMA1 | c.2586G>A p.M862I (on ENST00000286628 / NM_001161352.2; = p.M804I on NM_002247.4) | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99695142; called by muse, mutect2, varscan2
- KCNU1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 50/600 reads (8%) | catalogued as COSV101298931; called by muse, mutect2
- KERA | c.618T>A p.N206K | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99899317; called by muse, mutect2, varscan2
- KHDRBS2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV55425428, COSV99831192; called by muse, mutect2, varscan2
- KIAA1217 | c.5607T>G p.H1869Q | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV100286223; called by muse, mutect2, varscan2
- KIF17 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.081); catalogued as COSV99928557; called by muse, mutect2, varscan2
- KIT | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99853352; called by muse, mutect2, varscan2
- KLHL28 | c.1460A>C p.H487P | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100752985; called by muse, mutect2, varscan2
- KLHL6 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV100384327, COSV100385110; called by muse, mutect2, varscan2
- KRTAP1-5 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.096); catalogued as COSV100721356, COSV62624171; called by muse, mutect2, varscan2
- LHX8 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99633122; called by muse, mutect2, varscan2
- LIPK | c.771C>G p.N257K | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV101344950; called by muse, mutect2, varscan2
- LPCAT4 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148843; called by muse, mutect2, varscan2
- LRFN2 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV100599125; called by muse, mutect2, varscan2
- LRP1B | c.12389G>T p.G4130V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101252970, COSV67229281; called by muse, mutect2, varscan2
- LRRC18 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV99628505; called by muse, mutect2, varscan2
- LRRC4C | c.1694C>A p.T565N | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV99537053; called by muse, mutect2, varscan2
- MAGEA1 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100756610; called by muse, mutect2
- MAGEB10 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV100775150; called by muse, mutect2, varscan2
- MAGEC1 | c.2339G>T p.S780I | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV99594893; called by muse, mutect2, varscan2
- MAGEC3 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs552092345, COSV100024907; called by muse, mutect2, varscan2
- MAGI3 | c.1472G>C p.C491S | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100288138; called by muse, mutect2
- MAP2K6 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 43/191 reads (23%) | catalogued as COSV100765038; called by muse, mutect2, varscan2
- MBD5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101289956; called by muse, mutect2, varscan2
- MCTS1 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100989133; called by muse, mutect2, varscan2
- MED12 | c.5138G>C p.R1713P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99048841; called by muse, mutect2, varscan2
- MGAM | c.3705del p.P1236Lfs*2 | Frame Shift Del (DEL) | VAF 280/558 reads (50%) | catalogued as COSV72074499, COSV72075046; called by mutect2, varscan2
- MINDY4 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1462875022, COSV54678221, COSV99518222, COSV99518349; called by muse, mutect2, varscan2
- MMP20 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99497447; called by muse, mutect2, varscan2
- MMS22L | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99246148; called by muse, mutect2, varscan2
- MORC4 | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 206/668 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV99716835; called by muse, mutect2, varscan2
- MRPS15 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV64152694; called by muse, mutect2, varscan2
- MXD3 | c.307A>G p.R103G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100293463; called by muse, mutect2, varscan2
- MYBPC1 | c.2704G>T p.E902* (on ENST00000550270 / NM_206820.2; = p.E909* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 114/313 reads (36%) | catalogued as COSV100637759; called by muse, mutect2, varscan2
- MYL5 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1451332319, COSV100448346; called by muse, mutect2
- MYO1H | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100183131, COSV60448338; called by muse, mutect2
- MYO1H | c.1009A>T p.R337* | Nonsense Mutation (SNP) | VAF 47/304 reads (15%) | catalogued as COSV100183133; called by muse, mutect2, varscan2
- NAV3 | c.1337T>A p.L446* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as COSV99887182; called by muse, mutect2, varscan2
- NAV3 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 78/429 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57084970, COSV99886244; called by muse, mutect2, varscan2
- NAV3 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 69/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57090774, COSV99887188; called by muse, mutect2, varscan2
- NCBP2L | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 154/446 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966479; called by muse, mutect2, varscan2
- NEXMIF | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 119/621 reads (19%) | catalogued as COSV50022151, COSV99279709; called by muse, mutect2, varscan2
- NF1 | c.6536G>T p.R2179L (on ENST00000358273 / NM_001042492.3; = p.R2158L on NM_000267.3) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs772639479, COSV100646073; called by muse, mutect2, varscan2
- NGDN | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV101238832; called by muse, mutect2, varscan2
- NLGN1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV100848773; called by muse, mutect2, varscan2
- NLGN1 | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848774; called by muse, mutect2, varscan2
- NLRP14 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV100204589; called by muse, mutect2
- NLRP3 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 97/523 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100275300; called by muse, mutect2, varscan2
- NLRP3 | c.2472G>T p.L824F | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760112424, COSV100275303; called by muse, mutect2, varscan2
- NLRP4 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV56712791; called by muse, mutect2
- NLRP5 | c.2755A>G p.R919G | Missense Mutation (SNP) | VAF 65/654 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101173392; called by muse, mutect2, varscan2
- NLRP5 | c.3409A>G p.K1137E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101173393; called by muse, mutect2
- NRK | c.4729C>A p.Q1577K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99686650; called by muse, mutect2, varscan2
- NUP160 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101021312; called by muse, mutect2, varscan2
- OGDHL | c.2754G>T p.Q918H | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100934206, COSV65102466; called by muse, mutect2, varscan2
- OLR1 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376294; called by muse, mutect2, varscan2
- OPN1LW | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV100886853; called by muse, mutect2, varscan2
- OR10A3 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.745); catalogued as COSV100660222; called by muse, mutect2, varscan2
- OR10K1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 111/886 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99193230; called by muse, mutect2, varscan2
- OR10K2 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 85/1058 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as COSV59222412, COSV59222806; called by muse, mutect2
- OR10S1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101602444; called by muse, mutect2, varscan2
- OR2T12 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.71); catalogued as COSV100527544; called by muse, mutect2, varscan2
- OR2T3 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100613091; called by muse, mutect2, varscan2
- OR4A47 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as rs1472091465, COSV101487051; called by muse, mutect2, varscan2
- OR4B1 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 120/481 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100535486; called by muse, mutect2, varscan2
- OR4C12 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 104/1092 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100078282; called by muse, mutect2
- OR4K2 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 29/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100064102; called by muse, mutect2
- OR4N5 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 173/686 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61321553; called by muse, mutect2, varscan2
- OR4Q3 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100056729; called by muse, mutect2
- OR5B17 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs775710411, COSV100641854; called by muse, mutect2, varscan2
- OR5D16 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 54/495 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004098, COSV65721938; called by muse, mutect2, varscan2
- OR5L1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 138/565 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100449927; called by muse, mutect2, varscan2
- OR8A1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99420335; called by muse, mutect2, varscan2
- OR8H3 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100538753, COSV57910130; called by muse, mutect2, varscan2
- OR9G4 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 87/487 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100265007; called by muse, mutect2, varscan2
- OTOA | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 140/519 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99623635; called by muse, mutect2, varscan2
- P2RY4 | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996974; called by muse, mutect2, varscan2
- PARVG | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100796028; called by muse, mutect2
- PCDH11X | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100008489, COSV53454550; called by muse, mutect2, varscan2
- PCDHA5 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100972118; called by muse, mutect2, varscan2
- PCDHB14 | c.67T>A p.L23M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.04); catalogued as COSV99505572; called by mutect2, varscan2
- PCDHGA12 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52751495, COSV99338251; called by muse, mutect2, varscan2
- PCLO | c.12094G>T p.D4032Y | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61667325; called by muse, mutect2, varscan2
- PDE1C | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100371120; called by muse, mutect2, varscan2
- PDE3A | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100761693; called by muse, mutect2, varscan2
- PDE4DIP | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 273/505 reads (54%) | catalogued as COSV100516752; called by muse, mutect2, varscan2
- PDE8B | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99366187; called by muse, mutect2, varscan2
- PDE9A | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99371082; called by muse, mutect2, varscan2
- PDLIM5 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as COSV100523354, COSV58747786; called by muse, mutect2, varscan2
- PDYN | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV99452709; called by muse, mutect2, varscan2
- PEAK1 | c.3268G>T p.G1090* | Nonsense Mutation (SNP) | VAF 42/161 reads (26%) | catalogued as COSV100432468; called by muse, mutect2, varscan2
- PHC3 | c.751A>T p.T251S (on ENST00000494943 / NM_001308116.2; = p.T263S on NM_024947.4) | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV101520141; called by muse, mutect2, varscan2
- PHKA2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101176659; called by muse, mutect2, varscan2
- PHKB | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100065639; called by muse, mutect2, varscan2
- PIGO | c.2312C>G p.A771G | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV99956425; called by muse, mutect2
- PIGO | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1166737574, COSV99956428; called by muse, mutect2
- PIH1D1 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV99221012; called by muse, mutect2, varscan2
- PIK3C3 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV100010362; called by muse, mutect2, varscan2
- PIK3C3 | c.1325+1G>T p.X442_splice | Splice Site (SNP) | VAF 21/203 reads (10%) | catalogued as COSV100010363; called by muse, mutect2, varscan2
- PIWIL1 | c.729T>G p.S243R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99806015; called by mutect2, varscan2
- PLD5 | c.356G>T p.G119V (on ENST00000442594; = p.G57V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100138876; called by muse, mutect2, varscan2
- PLD5 | c.355G>C p.G119R (on ENST00000442594; = p.G57R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100138879; called by muse, mutect2, varscan2
- PLPP2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99514468; called by muse, mutect2, varscan2
- PLXNA3 | c.2831G>T p.R944L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1193337165, COSV100859818, COSV63753753; called by muse, mutect2, varscan2
- PMS1 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100575464; called by muse, mutect2, varscan2
- POLA1 | c.153C>A p.V51= | Splice Region (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100985039; called by muse, mutect2, varscan2
- POTEM | c.940T>A p.C314S | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.329); catalogued as rs1394704291; called by muse, mutect2, varscan2
- PPM1K | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99900851; called by muse, varscan2
- PPP1R16B | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55380372; called by muse, mutect2, varscan2
- PREX2 | c.4052A>T p.Y1351F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99905249; called by muse, mutect2, varscan2
- PRKD1 | c.1673-1G>T p.X558_splice | Splice Site (SNP) | VAF 57/199 reads (29%) | catalogued as COSV100119328; called by muse, mutect2, varscan2
- PRLR | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99184214; called by muse, mutect2, varscan2
- PRPF3 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100254502; called by muse, mutect2
- PRR19 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100003642; called by muse, mutect2, varscan2
- PRSS35 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100864035; called by muse, mutect2, varscan2
- PTPRD | c.5552C>A p.T1851N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643468; called by muse, mutect2, varscan2
- PTPRD | c.5513G>A p.G1838E | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100643471; called by muse, mutect2, varscan2
- PTPRE | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV99616964; called by muse, mutect2, varscan2
- PTPRO | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99839778; called by muse, mutect2, varscan2
- RALGPS2 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV100243550; called by muse, mutect2, varscan2
- RASGEF1C | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs760031898, COSV63186161; called by muse, mutect2, varscan2
- RFX4 | c.1363C>A p.L455I (on ENST00000392842 / NM_213594.3; = p.L361I on NM_032491.6) | Missense Mutation (SNP) | VAF 123/551 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99985398; called by muse, mutect2, varscan2
- RFX6 | c.2596C>G p.R866G | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as CM1512294, COSV100263268, COSV60584562; called by muse, mutect2, varscan2
- RHBG | c.690G>C p.W230C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99659173; called by muse, mutect2
- RHEX | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 34/133 reads (26%) | catalogued as rs1306431885, COSV100520016; called by muse, mutect2, varscan2
- RTL9 | c.2197A>T p.M733L | Missense Mutation (SNP) | VAF 208/554 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101511626; called by muse, mutect2, varscan2
- RYR2 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100768163; called by muse, mutect2, varscan2
- SALL1 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV99171577, COSV99192553; called by muse, mutect2, varscan2
- SALL1 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758651425, COSV51759369; called by muse, varscan2
- SATL1 | c.10C>A p.P4T (on ENST00000395409; = p.P191T on NM_001012980.2) | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV100260679; called by muse, mutect2, varscan2
- SCN8A | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 191/832 reads (23%) | catalogued as rs1555214322, COSV61989293; called by muse, mutect2, varscan2
- SEC14L3 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs752658817, COSV53179955, COSV99306937; called by mutect2, varscan2
- SETD5 | c.3337C>A p.H1113N | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100200177; called by muse, mutect2, varscan2
- SHANK1 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99520277; called by muse, mutect2, varscan2
- SHROOM2 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101098180; called by muse, mutect2, varscan2
- SI | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100014158; called by muse, mutect2, varscan2
- SIAE | c.1075T>G p.F359V | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99422177; called by muse, mutect2, varscan2
- SIX6 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.163); catalogued as rs1383480571, COSV100576440; called by mutect2, varscan2
- SLC16A5 | c.1080T>A p.D360E | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.356); catalogued as COSV100316976; called by muse, mutect2, varscan2
- SLC16A9 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101264314; called by muse, mutect2, varscan2
- SLC17A2 | c.1259C>T p.A420V (on ENST00000265425; = p.Q371* on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99613921; called by muse, mutect2, varscan2
- SLC22A3 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780018864, COSV51718519; called by muse, mutect2, varscan2
- SLC22A3 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278360; called by muse, mutect2, varscan2
- SLC25A39 | c.1060G>T p.D354Y (on ENST00000377095 / NM_001143780.3; = p.D346Y on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99835120; called by muse, mutect2
- SLC39A6 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99309377; called by muse, mutect2, varscan2
- SLC4A3 | c.2348G>T p.R783L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV99812439; called by muse, mutect2, varscan2
- SLC6A14 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.936); catalogued as COSV100903067, COSV100903147; called by muse, mutect2, varscan2
- SLC7A3 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99979339; called by muse, mutect2, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 26/241 reads (11%) | catalogued as rs748701652; called by mutect2, varscan2
- SLC9A4 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99762729; called by muse, mutect2, varscan2
- SLCO1A2 | c.1399G>C p.A467P | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100261356; called by muse, mutect2, varscan2
- SLCO1C1 | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1262628085, COSV99858502; called by muse, mutect2, varscan2
- SLCO1C1 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299681114, COSV99858509; called by muse, mutect2, varscan2
- SLF2 | c.1808G>T p.S603I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99488515; called by muse, mutect2, varscan2
- SLIT2 | c.3871G>T p.A1291S | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.057); catalogued as rs765899590, COSV99881147; called by muse, mutect2, varscan2
- SLITRK4 | c.565A>T p.R189* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV100567167; called by muse, mutect2, varscan2
- SLITRK5 | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100280334, COSV61522304; called by muse, mutect2, varscan2
- SNX30 | c.1224G>T p.M408I | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100953751; called by muse, mutect2, varscan2
- SPTB | c.3502C>A p.L1168I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.273); catalogued as rs145875201; called by muse, mutect2, varscan2
- SQOR | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99525525; called by muse, mutect2, varscan2
- SRD5A3 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 164/507 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99947987; called by muse, mutect2, varscan2
- SRGAP1 | c.2659C>A p.P887T | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV100754282; called by muse, mutect2, varscan2
- SRGAP3 | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100840730; called by muse, mutect2, varscan2
- ST8SIA1 | c.254G>C p.C85S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99682770; called by muse, mutect2, varscan2
- ST8SIA2 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 31/259 reads (12%) | PolyPhen benign (0); catalogued as COSV99184370; called by muse, mutect2, varscan2
- STARD4 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99685226; called by muse, mutect2, varscan2
- STON1 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 51/263 reads (19%) | catalogued as COSV100561495; called by muse, mutect2, varscan2
- SUGCT | c.560A>T p.H187L | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100000073, COSV59348335; called by muse, mutect2, varscan2
- SYT12 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375154870; called by muse, mutect2, varscan2
- SZT2 | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100986895; called by muse, varscan2
- TAOK1 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 34/183 reads (19%) | catalogued as COSV99913550; called by muse, mutect2, varscan2
- TBC1D9B | c.3421C>G p.Q1141E (on ENST00000356834 / NM_198868.3; = p.Q1124E on NM_015043.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.038); catalogued as COSV99481312; called by muse, mutect2, varscan2
- TCEAL6 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101035909, COSV65653934; called by muse, mutect2, varscan2
- TCN1 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99953098; called by muse, mutect2, varscan2
- TECTA | c.3781T>A p.S1261T | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99878691; called by muse, varscan2
- TENM1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 272/1069 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.294); catalogued as COSV100949130; called by muse, mutect2, varscan2
- TEX44 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100009598; called by muse, mutect2, varscan2
- TFDP3 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100033205; called by muse, mutect2
- THOC2 | c.3868C>A p.P1290T | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs772379634, COSV55542725, COSV55554704; called by muse, mutect2, varscan2
- TICRR | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV99176033; called by muse, mutect2, varscan2
- TLL2 | c.1064T>G p.L355R | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100780135; called by muse, mutect2, varscan2
- TM9SF2 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100816398; called by muse, mutect2, varscan2
- TMCO5A | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 46/573 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100148442; called by muse, mutect2
- TMEM117 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861886; called by muse, mutect2, varscan2
- TMEM131 | c.5614G>T p.D1872Y | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1262976582, COSV99486639; called by muse, mutect2, varscan2
- TNR | c.3243C>A p.S1081R | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV54897139; called by muse, mutect2
- TNR | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as COSV99687740; called by muse, mutect2, varscan2
- TOGARAM1 | c.2501T>C p.I834T | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100817831; called by muse, mutect2, varscan2
- TPH1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100000650; called by muse, mutect2, varscan2
- TRIM42 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99647997; called by muse, mutect2, varscan2
- TRIM42 | c.1866C>A p.Y622* | Nonsense Mutation (SNP) | VAF 89/357 reads (25%) | catalogued as COSV99648001; called by muse, mutect2, varscan2
- TRIM56 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781156766, COSV100046983; called by muse, mutect2, varscan2
- TRIM58 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 147/441 reads (33%) | catalogued as rs1349504673, COSV63569515, COSV63571737; called by muse, mutect2, varscan2
- TRIP12 | c.5603G>T p.G1868V | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389426; called by muse, mutect2
- TRPC5 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53287122; called by muse, mutect2, varscan2
- TSC22D1 | c.266C>G p.S89W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV101488067; called by muse, mutect2, varscan2
- TSPEAR | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100390176; called by muse, mutect2
- TTC14 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV99931825; called by muse, mutect2, varscan2
- TTN | c.39650C>G p.P13217R (on ENST00000591111; = p.P5793R on NM_003319.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100595545; called by muse, mutect2, varscan2
- TTN | c.36556G>T p.V12186L (on ENST00000591111; = p.V4762L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | PolyPhen benign (0.053); catalogued as COSV100595548; called by muse, mutect2, varscan2
- TTN | c.6535G>T p.E2179* (on ENST00000591111; = p.E2133* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 62/259 reads (24%) | catalogued as COSV100595553, COSV60177877; called by muse, mutect2, varscan2
- TUBB4A | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99899875; called by muse, mutect2, varscan2
- TXNDC11 | c.2328T>A p.S776R (on ENST00000356957 / NM_001303447.2; = p.S749R on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99297289; called by muse, mutect2, varscan2
- UNC79 | c.4325C>A p.A1442D (on ENST00000393151 / NM_001346218.2; = p.A1265D on NM_020818.5) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99825976; called by muse, mutect2, varscan2
- UPK1A | c.84G>C p.L28= | Splice Region (SNP) | VAF 31/107 reads (29%) | catalogued as COSV99721770; called by muse, mutect2, varscan2
- USP10 | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 46/211 reads (22%) | catalogued as COSV54749705; called by muse, mutect2
- UTP25 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 99/627 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200728349, COSV71965910; called by muse, mutect2, varscan2
- WWC3 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 125/443 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV101081069; called by muse, mutect2, varscan2
- XIRP2 | c.1325C>G p.T442S (on ENST00000628543; = p.T617S on NM_152381.6) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs776944687, COSV54685810, COSV99738796; called by muse, mutect2, varscan2
- XKR7 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1287211370, COSV101629234; called by muse, varscan2
- ZCCHC7 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382797; called by muse, mutect2, varscan2
- ZEB2 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100355051, COSV57956872; called by muse, mutect2, varscan2
- ZNF292 | c.7726G>T p.E2576* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100369808; called by muse, mutect2, varscan2
- ZNF416 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99543692; called by muse, mutect2
- ZNF449 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 60/661 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100202819; called by muse, mutect2
- ZNF479 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 58/251 reads (23%) | catalogued as rs1192313145, COSV58643700; called by muse, varscan2
- ZNF584 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV59723191; called by muse, mutect2, varscan2
- ZNF711 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99340667; called by mutect2, varscan2
- ZNF777 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99925003; called by muse, varscan2
- ZNF787 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99555350; called by muse, mutect2, varscan2
- ZNF836 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV100440624; called by muse, mutect2, varscan2
- ACACA | c.2891G>T p.S964I | Missense Mutation (SNP) | VAF 126/584 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AFF2 | c.1414delinsAA p.P472Nfs*24 | Frame Shift Ins (INS) | VAF 35/282 reads (12%) | called by pindel, varscan2*
- AMER1 | c.3136G>T p.A1046S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by mutect2, varscan2
- ARAP2 | c.1076del p.G359Efs*29 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- C2CD3 | c.3198_3199del p.V1068Sfs*6 | Frame Shift Del (DEL) | VAF 134/510 reads (26%) | called by pindel, varscan2
- CUBN | c.4734del p.R1579Gfs*21 | Frame Shift Del (DEL) | VAF 65/281 reads (23%) | called by mutect2, pindel, varscan2
- FRG2C | c.322del p.Q108Kfs*14 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- FRMD4B | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FSHR | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); called by muse, mutect2
- GET4 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IGHV3-21 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.361); called by muse, mutect2
- MRC1 | c.4301C>A p.S1434* | Nonsense Mutation (SNP) | VAF 85/763 reads (11%) | called by muse, mutect2, varscan2
- MYO19 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR2B11 | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 81/1874 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- OR2C3 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR4A47 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- OR4C11 | c.24_45del p.E9Hfs*5 | Frame Shift Del (DEL) | VAF 31/322 reads (10%) | called by mutect2, pindel
- OR8B8 | c.439_440delinsA p.G147Mfs*17 | Frame Shift Del (DEL) | VAF 44/305 reads (14%) | called by pindel, varscan2*
- PRRC2A | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RASA3 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.046); called by muse, mutect2
- RELB | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RGS18 | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTL3 | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINF1 | c.1011G>T p.L337F | Missense Mutation (SNP) | VAF 41/712 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); called by muse, mutect2
- SPRY3 | c.843del p.K282Rfs*37 | Frame Shift Del (DEL) | VAF 57/352 reads (16%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4598G>T p.G1533V (on ENST00000367255 / NM_182961.4; = p.G1540V on NM_033071.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- TCF12 | c.668del p.S223Tfs*22 | Frame Shift Del (DEL) | VAF 59/373 reads (16%) | called by mutect2, pindel, varscan2
- TPTE | c.706G>C p.D236H (on ENST00000618007 / NM_199261.4; = p.D218H on NM_199259.4) | Missense Mutation (SNP) | VAF 122/2750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV26-2 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRBC2 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.5724T>C p.H1908= | Silent (SNP) | VAF 30/239 reads (13%) | catalogued as rs770187952, COSV101329933; called by muse, mutect2, varscan2
- AMER1 | c.528C>A p.I176= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100365365; called by muse, mutect2, varscan2
- APCDD1L | c.903C>T p.L301= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- ATP10A | c.4443A>G p.G1481= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as COSV100790899; called by muse, mutect2, varscan2
- ATP23 | c.457C>A p.R153= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs867626853, COSV100274414; called by muse, mutect2, varscan2
- BBOX1 | c.825T>C p.H275= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99589445; called by muse, mutect2
- BMS1 | c.93A>T p.L31= | Silent (SNP) | VAF 60/236 reads (25%) | catalogued as COSV100996484; called by muse, mutect2, varscan2
- BPIFB6 | c.675G>A p.V225= | Silent (SNP) | VAF 57/309 reads (18%) | catalogued as rs760488590, COSV100848486; called by muse, mutect2, varscan2
- BRWD3 | c.3447G>T p.R1149= | Silent (SNP) | VAF 37/208 reads (18%) | catalogued as COSV100955668; called by muse, mutect2, varscan2
- C7 | c.1308G>C p.V436= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as COSV100495432, COSV57470929, COSV57479187; called by muse, mutect2, varscan2
- C8A | c.1614A>G p.A538= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100776443; called by muse, mutect2, varscan2
- CCDC18 | c.3819G>A p.L1273= (on ENST00000343253 / NM_001306076.1; = p.L1274= on NM_206886.4) | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as COSV100159241; called by muse, mutect2, varscan2
- CCT8L2 | c.573C>A p.I191= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100742569; called by muse, mutect2, varscan2
- CD5 | c.1449C>T p.S483= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs779186136, COSV57109272; called by muse, mutect2, varscan2
- CDH11 | c.843C>A p.A281= | Silent (SNP) | VAF 151/527 reads (29%) | catalogued as COSV51768799, COSV99217306; called by muse, mutect2, varscan2
- CDH9 | c.408G>T p.G136= | Silent (SNP) | VAF 105/370 reads (28%) | catalogued as COSV99141855; called by muse, mutect2, varscan2
- CEMIP | c.3186C>G p.P1062= | Silent (SNP) | VAF 38/225 reads (17%) | catalogued as COSV99586133, COSV99587483; called by muse, mutect2, varscan2
- CFHR4 | c.1308C>A p.S436= (on ENST00000367416 / NM_001201551.2; = p.S190= on NM_006684.5) | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV52231709, COSV99259590; called by muse, mutect2, varscan2
- CSMD1 | c.7824G>T p.T2608= (on ENST00000520002; = p.T2607= on NM_033225.6) | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs746936196, COSV100144233, COSV100151547; called by muse, mutect2, varscan2
- CSMD1 | c.2640T>A p.P880= (on ENST00000520002; = p.P879= on NM_033225.6) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100144234; called by muse, mutect2, varscan2
- DEPDC5 | c.2556T>C p.S852= (on ENST00000400246; = p.S921= on NM_014662.5) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99834443; called by muse, mutect2, varscan2
- DNAH11 | c.3459A>G p.T1153= | Silent (SNP) | VAF 119/302 reads (39%) | catalogued as COSV100177355; called by muse, mutect2, varscan2
- EIF2AK2 | c.879C>T p.Y293= | Silent (SNP) | VAF 86/433 reads (20%) | catalogued as rs757581996, COSV99240328; called by muse, mutect2, varscan2
- ELAVL2 | c.849G>C p.L283= | Silent (SNP) | VAF 64/171 reads (37%) | catalogued as COSV99805499; called by muse, mutect2, varscan2
- EPHA7 | c.2796A>G p.L932= | Silent (SNP) | VAF 56/209 reads (27%) | catalogued as COSV100993290; called by muse, mutect2, varscan2
- FAM110B | c.1014G>C p.V338= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100826020; called by muse, mutect2, varscan2
- FAM135B | c.837T>G p.V279= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99419324; called by muse, mutect2, varscan2
- FAT4 | c.7548C>T p.H2516= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100627303; called by muse, mutect2, varscan2
- FBXL4 | c.1554G>A p.L518= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV100013829, COSV100013879; called by muse, mutect2, varscan2
- FCHSD1 | c.1660C>T p.L554= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99781174; called by muse, mutect2, varscan2
- FER | c.333G>A p.K111= | Silent (SNP) | VAF 169/547 reads (31%) | catalogued as COSV99811697; called by muse, mutect2, varscan2
- GBA | c.837G>T p.L279= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as rs371576958, COSV59171311; called by muse, mutect2, varscan2
- GBP5 | c.252T>A p.P84= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as COSV100599983; called by muse, mutect2, varscan2
- GCN1 | c.5229C>T p.A1743= | Silent (SNP) | VAF 73/241 reads (30%) | catalogued as COSV100324690; called by muse, mutect2, varscan2
- GRID2 | c.2472C>T p.G824= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as rs771961200, COSV56212046, COSV56245706; called by muse, mutect2, varscan2
- HUWE1 | c.9219C>A p.V3073= | Silent (SNP) | VAF 24/301 reads (8%) | catalogued as COSV99470738; called by muse, mutect2
- IGLV3-32 | c.117C>A p.T39= | Silent (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- IL10RA | c.1191C>A p.G397= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99922881; called by muse, mutect2, varscan2
- INTS6L | c.2313T>A p.P771= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV100878019; called by muse, mutect2, varscan2
- IREB2 | c.2223T>C p.H741= | Silent (SNP) | VAF 81/248 reads (33%) | catalogued as rs1041096900, COSV51920773; called by muse, mutect2, varscan2
- KANK4 | c.345C>T p.A115= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100587046; called by muse, mutect2, varscan2
- KCNH6 | c.771C>A p.A257= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV100120802; called by muse, mutect2, varscan2
- KIT | c.333T>C p.V111= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99853351; called by muse, mutect2, varscan2
- KRT2 | c.465C>T p.V155= | Silent (SNP) | VAF 44/204 reads (22%) | catalogued as COSV59013349; called by muse, mutect2, varscan2
- KRT25 | c.630G>T p.L210= | Silent (SNP) | VAF 125/526 reads (24%) | catalogued as COSV100379813; called by muse, varscan2
- KY | c.1134G>A p.T378= | Silent (SNP) | VAF 35/269 reads (13%) | catalogued as COSV101414943; called by muse, mutect2, varscan2
- LIPG | c.708G>T p.V236= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV99724278; called by muse, mutect2, varscan2
- LPAR4 | c.678G>T p.V226= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV101425077; called by muse, mutect2, varscan2
- MAP4K4 | c.960G>A p.E320= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs369103675; called by muse, mutect2, varscan2
- MCF2 | c.1692G>T p.L564= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV100644317; called by muse, mutect2, varscan2
- MED12 | c.2874G>A p.G958= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs773333573, COSV100376259; called by muse, mutect2
- MUC16 | c.17355G>A p.R5785= | Silent (SNP) | VAF 163/446 reads (37%) | catalogued as COSV101198276; called by muse, mutect2, varscan2
- MUC4 | c.2505C>T p.S835= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs752724482, COSV100639592; called by muse, mutect2, varscan2
- MYH9 | c.4494C>T p.L1498= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- MYO1A | c.2955G>T p.R985= | Silent (SNP) | VAF 59/249 reads (24%) | catalogued as COSV100270604; called by muse, mutect2, varscan2
- MYO3A | c.2709G>T p.L903= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99778475; called by muse, mutect2
- MYOC | c.315C>T p.D105= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99231314; called by muse, mutect2, varscan2
- N4BP1 | c.1581C>T p.H527= | Silent (SNP) | VAF 14/372 reads (4%) | catalogued as rs1382457041; called by muse, mutect2
- NCAPH | c.126G>T p.A42= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs139287054, COSV99545546; called by muse, mutect2, varscan2
- NCKAP1L | c.78C>T p.L26= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV53209039; called by muse, mutect2, varscan2
- NHSL2 | c.1017C>A p.P339= (on ENST00000510661; = p.P705= on NM_001013627.2) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV101029892; called by muse, mutect2, varscan2
- NLRP13 | c.1461C>A p.A487= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV100738048; called by muse, mutect2, varscan2
- OR1C1 | c.387C>A p.P129= | Silent (SNP) | VAF 65/416 reads (16%) | catalogued as COSV101376185, COSV68715511; called by muse, mutect2, varscan2
- OR2G6 | c.837C>T p.T279= | Silent (SNP) | VAF 35/247 reads (14%) | catalogued as COSV100598035; called by muse, mutect2, varscan2
- OR5M8 | c.873T>A p.L291= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100510552; called by muse, mutect2, varscan2
- OR6K3 | c.279C>A p.T93= (on ENST00000368146; = p.T77= on NM_001005327.2) | Silent (SNP) | VAF 403/1050 reads (38%) | catalogued as COSV100933833; called by muse, mutect2, varscan2
- OR6S1 | c.483C>A p.P161= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100289279; called by muse, mutect2, varscan2
- OR8B8 | c.420G>C p.V140= | Silent (SNP) | VAF 60/298 reads (20%) | catalogued as COSV100044836; called by muse, varscan2
- OSBPL3 | c.1668G>A p.L556= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as COSV100513718; called by muse, mutect2
- OTX1 | c.456A>T p.A152= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99246164; called by muse, varscan2
- PARP8 | c.741C>T p.I247= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99890058; called by muse, mutect2, varscan2
- PIGO | c.2925C>A p.P975= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- PM20D2 | c.1026T>C p.D342= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV99248206; called by muse, mutect2, varscan2
- PRDM2 | c.3873C>T p.L1291= | Silent (SNP) | VAF 17/514 reads (3%) | called by muse, mutect2
- PRPH | c.1128G>C p.L376= | Silent (SNP) | VAF 17/49 reads (35%) | called by mutect2, varscan2
- PSME1 | c.628C>A p.R210= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99246023; called by muse, mutect2, varscan2
- PTPRU | c.183G>T p.R61= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100111737; called by muse, mutect2, varscan2
- PYGL | c.2223G>A p.L741= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV99368270; called by muse, mutect2, varscan2
- RAG1 | c.2766C>A p.L922= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV100200671; called by muse, mutect2, varscan2
- RPS6KA6 | c.1041C>T p.F347= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV53123670, COSV99424137; called by muse, mutect2, varscan2
- SACS | c.10107C>A p.V3369= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101207185, COSV101207668; called by muse, mutect2
- SASH3 | c.393T>A p.S131= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100795158; called by muse, mutect2, varscan2
- SAXO1 | c.102C>A p.L34= | Silent (SNP) | VAF 27/495 reads (5%) | catalogued as COSV101000105, COSV65871050; called by muse, mutect2
- SERPINA3 | c.153C>G p.S51= | Silent (SNP) | VAF 54/210 reads (26%) | catalogued as COSV101261613, COSV67587407; called by muse, mutect2
- SI | c.2280T>A p.A760= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100014156; called by muse, mutect2, varscan2
- SMYD1 | c.162C>A p.T54= | Silent (SNP) | VAF 74/279 reads (27%) | catalogued as COSV101352398; called by muse, mutect2, varscan2
- SYN3 | c.489G>T p.L163= | Silent (SNP) | VAF 82/363 reads (23%) | catalogued as COSV100248395; called by muse, mutect2, varscan2
- TBC1D15 | c.108A>T p.G36= | Silent (SNP) | VAF 104/453 reads (23%) | catalogued as COSV100041396; called by muse, mutect2, varscan2
- TECRL | c.627A>G p.A209= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV101168486; called by muse, mutect2, varscan2
- THSD7A | c.3849C>T p.C1283= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV101439722; called by muse, mutect2, varscan2
- THSD7A | c.306C>G p.A102= | Silent (SNP) | VAF 89/201 reads (44%) | catalogued as COSV101448551, COSV101448836, COSV70261039; called by muse, mutect2, varscan2
- TMED2 | c.150G>T p.A50= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV51629776, COSV99147721; called by muse, mutect2, varscan2
- TOX2 | c.1317C>A p.I439= (on ENST00000358131 / NM_001098798.2; = p.I415= on NM_032883.3) | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as COSV100363375; called by muse, mutect2, varscan2
- TTN | c.44514C>A p.G14838= (on ENST00000591111; = p.G7414= on NM_003319.4) | Silent (SNP) | VAF 86/403 reads (21%) | catalogued as COSV100595543; called by muse, mutect2, varscan2
- TXNDC16 | c.1954C>T p.L652= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV99908849; called by muse, mutect2, varscan2
- UPF2 | c.1635G>A p.K545= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100706950, COSV100707038, COSV62660784; called by muse, mutect2
- UTP14A | c.55C>T p.L19= | Silent (SNP) | VAF 19/213 reads (9%) | catalogued as COSV100930396; called by muse, mutect2
- VPS11 | c.750G>T p.R250= (on ENST00000620429; = p.R794= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100333537; called by muse, mutect2, varscan2
- WRAP53 | c.834G>A p.T278= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs372166304; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- XPNPEP2 | c.807A>G p.T269= | Silent (SNP) | VAF 128/516 reads (25%) | catalogued as COSV100941154; called by muse, mutect2, varscan2
- YIPF4 | c.279A>T p.R93= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99479729; called by muse, mutect2, varscan2
- ZEB1 | c.1752T>C p.P584= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as COSV100313675; called by muse, mutect2, varscan2
- ZNF644 | c.2133T>C p.I711= | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as COSV100494274; called by muse, mutect2, varscan2
- ZNF676 | c.249A>G p.Q83= (on ENST00000650058; = p.Q51= on NM_001001411.3) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101236102; called by muse, mutect2, varscan2
- ANKRD13D | c.*463A>T | 3'UTR (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100398283; called by muse, mutect2, varscan2
- CD300LD | chr17:74592750 C>T | 5'Flank (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- ERBB4 | c.82+112101G>T | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as rs1307091997, COSV99616962; called by muse, mutect2, varscan2
- IL36B | c.261+955C>A | Intron (SNP) | VAF 39/296 reads (13%) | catalogued as rs781159319, COSV99382488; called by muse, mutect2, varscan2
- MIR377 | n.34A>G | RNA (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- OR2W5 | n.644G>C | RNA (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-14 | n.53G>T | RNA (SNP) | VAF 114/562 reads (20%) | called by muse, mutect2, varscan2
- STMN2 | c.-2C>A | 5'UTR (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99626134; called by muse, mutect2, varscan2
- TMEM99 | n.890A>G | RNA (SNP) | VAF 14/110 reads (13%) | catalogued as rs1231061372, COSV100053971; called by muse, mutect2, varscan2
- USH1C | c.1285-7489C>A | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as COSV99139355; called by muse, varscan2
- YOD1 | chr1:207052208 C>G | 5'Flank (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100262866; called by muse, mutect2
